Somatic mutation profile of tumor specimen C3L-07645-05 (aliquot CPT0431740006) from CPTAC case C3L-07645, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 65.1 years (23,762 days).
Specimen C3L-07645-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddbc357d-14b3-4e94-905f-172c01a7ca39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07645-32 (Blood Derived Normal), aliquot CPT0431850003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/634b7a97-155e-4366-a217-d26bba9fb418

The open-access MAF lists 93 somatic variants for this specimen: 66 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 23, Frame Shift Del 4, RNA 3, In Frame Del 3, Nonsense Mutation 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM10 | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs753959279; called by muse, mutect2, varscan2
- BBS9 | c.1799G>A p.R600H (on ENST00000242067 / NM_001348036.1; = p.R560H on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749018243, COSV54189065; called by muse, mutect2, varscan2
- BPIFB1 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 83/661 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs759677300; called by muse, mutect2, varscan2
- CACNA1H | c.6002G>A p.R2001Q | Missense Mutation (SNP) | VAF 52/517 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs200399120; called by muse, mutect2, varscan2
- CRB1 | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs749366098, COSV66333419; called by muse, mutect2, varscan2
- EFL1 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs745854173; called by muse, mutect2, varscan2
- ENPEP | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 110/421 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs534876489, COSV54454922; called by muse, varscan2
- ESX1 | c.474C>A p.F158L | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV65425322; called by muse, mutect2
- GLE1 | c.1074G>C p.E358D | Missense Mutation (SNP) | VAF 30/416 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV59409487; called by muse, mutect2
- HHIPL1 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 97/338 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769018561; called by muse, mutect2, varscan2
- JPH3 | c.1816_1818del p.E606del | In Frame Del (DEL) | VAF 51/443 reads (12%) | catalogued as rs769602156; called by pindel, varscan2
- LRP2 | c.4876G>A p.D1626N | Missense Mutation (SNP) | VAF 59/317 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.531); catalogued as rs770638905, COSV55562035; called by muse, mutect2, varscan2
- MS4A15 | c.241A>C p.I81L | Missense Mutation (SNP) | VAF 40/462 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs758212378; called by muse, mutect2
- NCL | c.579_596del p.E193_D198del | In Frame Del (DEL) | VAF 72/382 reads (19%) | catalogued as rs747203154; called by mutect2, varscan2
- PRKACB | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as rs148797911; called by muse, mutect2, varscan2
- PRTFDC1 | c.491T>A p.M164K | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs762788561; called by muse, mutect2, varscan2
- PTPRK | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 48/610 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV63898893; called by muse, mutect2
- PXDN | c.4060C>T p.R1354W | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs565398993, COSV53230056; called by muse, mutect2, varscan2
- PXDN | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 120/625 reads (19%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.953); catalogued as rs370877087; called by muse, mutect2, varscan2
- SELENON | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 41/399 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138259627, COSV62525211; called by muse, mutect2
- SUGP2 | c.892A>T p.I298F | Missense Mutation (SNP) | VAF 42/418 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as rs545610582; called by muse, mutect2
- TEPP | c.478C>G p.R160G | Missense Mutation (SNP) | VAF 32/424 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.247); catalogued as COSV52042716; called by muse, mutect2
- TSSC4 | c.417G>T p.R139S | Missense Mutation (SNP) | VAF 70/528 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1488042207; called by muse, mutect2, varscan2
- UNC5A | c.1507G>A p.V503I | Missense Mutation (SNP) | VAF 43/341 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs755099198, COSV52838296; called by muse, mutect2, varscan2
- ZC3H3 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 76/819 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV52788414; called by muse, mutect2
- ZNF488 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 73/633 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.248); catalogued as rs782472727; called by muse, varscan2
- AHNAK2 | c.7195G>A p.G2399R | Missense Mutation (SNP) | VAF 54/560 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AQP11 | c.499G>T p.V167F | Missense Mutation (SNP) | VAF 41/511 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2
- ATR | c.1477A>T p.I493F | Missense Mutation (SNP) | VAF 95/295 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- BACH2 | c.1507C>A p.P503T | Missense Mutation (SNP) | VAF 62/568 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BTBD10 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 50/370 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, varscan2
- COL27A1 | c.4487G>A p.G1496E | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH17 | c.11890G>A p.V3964M | Missense Mutation (SNP) | VAF 97/403 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- EPHA3 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 52/465 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- FER1L5 | c.4003C>A p.L1335M (on ENST00000623019; = p.L1308M on NM_001293083.2) | Missense Mutation (SNP) | VAF 37/508 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); called by muse, mutect2
- GCN1 | c.4430A>G p.E1477G | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- GGH | c.868T>A p.S290T | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- GGN | c.831dup p.A278Cfs*39 | Frame Shift Ins (INS) | VAF 160/901 reads (18%) | called by mutect2, pindel, varscan2
- IQGAP1 | c.3745A>T p.S1249C | Missense Mutation (SNP) | VAF 136/316 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MEGF6 | c.2271G>T p.Q757H | Missense Mutation (SNP) | VAF 32/477 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); called by muse, mutect2
- MEP1B | c.1919G>C p.G640A | Missense Mutation (SNP) | VAF 398/701 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); called by muse, varscan2
- NMNAT3 | c.168A>C p.K56N (on ENST00000296202 / NM_001320512.1; = p.K19N on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/595 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2
- OSMR | c.2098A>G p.I700V | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PGR | c.2288T>A p.L763Q | Missense Mutation (SNP) | VAF 35/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PKD1L2 | c.1282C>T p.Q428* | Nonsense Mutation (SNP) | VAF 47/355 reads (13%) | called by muse, mutect2, varscan2
- POLD2 | c.569T>C p.L190P | Missense Mutation (SNP) | VAF 25/328 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- RAB11FIP5 | c.1018G>T p.G340W | Missense Mutation (SNP) | VAF 74/557 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- RESF1 | c.2701_2717del p.G901Ffs*16 | Frame Shift Del (DEL) | VAF 41/385 reads (11%) | called by mutect2, pindel
- RHPN2 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RTF2 | c.297G>A p.W99* | Nonsense Mutation (SNP) | VAF 36/528 reads (7%) | called by muse, mutect2
- SEMA5B | c.2959C>T p.R987W | Missense Mutation (SNP) | VAF 60/539 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIRPB1 | c.30_33del p.P11Vfs*5 | Frame Shift Del (DEL) | VAF 47/276 reads (17%) | called by mutect2, pindel, varscan2
- SLC12A5 | c.2917C>G p.R973G (on ENST00000454036 / NM_001134771.2; = p.R950G on NM_020708.5) | Missense Mutation (SNP) | VAF 182/519 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SNTG2 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 44/521 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); called by muse, mutect2
- SPINK8 | c.139_150del p.N47_W50del | In Frame Del (DEL) | VAF 41/212 reads (19%) | called by mutect2, pindel, varscan2
- TCN1 | c.301del p.A101Lfs*12 | Frame Shift Del (DEL) | VAF 31/267 reads (12%) | called by mutect2, pindel, varscan2
- TENM2 | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- TIAM1 | c.3106T>G p.S1036A | Missense Mutation (SNP) | VAF 79/427 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TPX2 | c.618del p.L207* | Frame Shift Del (DEL) | VAF 78/268 reads (29%) | called by mutect2, pindel, varscan2
- UNC80 | c.7063G>C p.A2355P | Missense Mutation (SNP) | VAF 61/339 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP32 | c.572T>G p.L191W | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- WDR5 | c.294T>G p.D98E | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- XCL1 | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- YY1AP1 | c.421C>G p.Q141E (on ENST00000295566 / NM_139118.2; = p.Q64E on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ZC3H6 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ZNF260 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 38/736 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.229); called by muse, mutect2
- ALDH3B2 | c.1011C>T p.T337= | Silent (SNP) | VAF 51/358 reads (14%) | catalogued as COSV100824071; called by muse, mutect2, varscan2
- AMY1C | c.954A>G p.R318= | Silent (SNP) | VAF 20/352 reads (6%) | called by muse, mutect2
- C10orf90 | c.1980G>A p.P660= | Silent (SNP) | VAF 20/296 reads (7%) | catalogued as rs200783026, COSV52950179; called by muse, mutect2
- DYM | c.1614C>T p.I538= | Silent (SNP) | VAF 131/1866 reads (7%) | catalogued as COSV53982239; called by muse, mutect2
- DYSF | c.3186G>A p.A1062= | Silent (SNP) | VAF 77/439 reads (18%) | catalogued as rs759829047, COSV50326146; called by muse, mutect2, varscan2
- FCAMR | c.969A>T p.T323= | Silent (SNP) | VAF 53/400 reads (13%) | catalogued as rs1314519663; called by muse, mutect2, varscan2
- GLI1 | c.1281C>T p.S427= | Silent (SNP) | VAF 39/309 reads (13%) | called by muse, mutect2, varscan2
- GPR149 | c.1032G>A p.E344= | Silent (SNP) | VAF 47/419 reads (11%) | catalogued as rs1193776057, COSV104432928; called by muse, mutect2, varscan2
- GRIN3A | c.3216G>C p.R1072= | Silent (SNP) | VAF 16/416 reads (4%) | called by muse, mutect2
- KLHL21 | c.111G>A p.V37= | Silent (SNP) | VAF 63/583 reads (11%) | called by muse, mutect2, varscan2
- LRP4 | c.339C>T p.D113= | Silent (SNP) | VAF 71/323 reads (22%) | catalogued as rs368971854; called by muse, mutect2, varscan2
- LRRC32 | c.1608G>A p.V536= | Silent (SNP) | VAF 49/604 reads (8%) | catalogued as rs1382157501, COSV52634918; called by muse, mutect2
- MAPK8IP3 | c.2388G>A p.V796= | Silent (SNP) | VAF 41/390 reads (11%) | called by muse, mutect2, varscan2
- MGAM | c.1866A>T p.A622= | Silent (SNP) | VAF 86/338 reads (25%) | called by muse, mutect2, varscan2
- NAGK | c.273G>C p.L91= | Silent (SNP) | VAF 75/384 reads (20%) | catalogued as rs17849402; called by muse, mutect2, varscan2
- NDUFS1 | c.1593G>A p.K531= | Silent (SNP) | VAF 52/337 reads (15%) | called by muse, mutect2, varscan2
- OTOG | c.7114C>T p.L2372= | Silent (SNP) | VAF 41/244 reads (17%) | called by muse, mutect2, varscan2
- SLC6A5 | c.252C>T p.S84= | Silent (SNP) | VAF 70/776 reads (9%) | catalogued as rs911887301; called by muse, mutect2
- TRPM8 | c.52C>T p.L18= | Silent (SNP) | VAF 34/394 reads (9%) | called by muse, mutect2
- WHRN | c.2061G>A p.P687= | Silent (SNP) | VAF 131/606 reads (22%) | catalogued as rs142268865; called by muse, mutect2, varscan2
- YIPF1 | c.304T>C p.L102= | Silent (SNP) | VAF 86/232 reads (37%) | called by muse, mutect2, varscan2
- ZNF441 | c.1461G>A p.L487= | Silent (SNP) | VAF 53/389 reads (14%) | called by muse, mutect2, varscan2
- ZNF512B | c.1662C>T p.G554= | Silent (SNP) | VAF 65/628 reads (10%) | called by muse, mutect2
- C14orf177 | n.689G>C | RNA (SNP) | VAF 39/408 reads (10%) | called by muse, mutect2, varscan2
- CCDC140 | n.860G>T | RNA (SNP) | VAF 44/209 reads (21%) | catalogued as rs778452993; called by muse, mutect2, varscan2
- KLHL1 | c.-234G>A | 5'UTR (SNP) | VAF 38/318 reads (12%) | called by muse, mutect2, varscan2
- MIAT | n.201A>C | RNA (SNP) | VAF 73/363 reads (20%) | called by muse, mutect2, varscan2
